Somatic mutation profile of tumor specimen TCGA-DE-A69K-01A (aliquot TCGA-DE-A69K-01A-11D-A397-08) from TCGA case TCGA-DE-A69K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 58.6 years (21,403 days).
Specimen TCGA-DE-A69K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cacb193-df3a-4e25-9f22-4ff874f9b537.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A69K-10A (Blood Derived Normal), aliquot TCGA-DE-A69K-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51bc268a-a16a-4e42-a1b1-3923740922f2

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF40 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100070681, COSV53880731; called by muse, mutect2, varscan2
- CELSR1 | c.4246G>C p.G1416R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99419942; called by muse, mutect2, varscan2
- CNR1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1482444652, COSV100759136; called by muse, mutect2, varscan2
- GAS2L3 | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99903150; called by muse, mutect2
- HAUS6 | c.311G>A p.C104Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1239720378, COSV100787227; called by muse, mutect2
- LRFN3 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV99873585; called by muse, mutect2
- PAXIP1 | c.2057T>G p.M686R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV101250068; called by muse, mutect2
- PRSS53 | c.211T>C p.W71R | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425315324, COSV99762649; called by muse, mutect2
- PTPRR | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.317); catalogued as rs370625173; called by muse, mutect2
- SV2C | c.1503A>T p.R501S | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as rs753185097, COSV100456790; called by muse, mutect2, varscan2
- CUX1 | c.674+3_674+6del p.X225_splice (on ENST00000292535 / NM_181552.4; = p.X236_splice on NM_001913.5) | Splice Site (DEL) | VAF 17/56 reads (30%) | called by pindel, varscan2
- KANK1 | c.3276A>G p.A1092= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs780639248, COSV100620089; called by muse, mutect2, varscan2
